TCGA case TCGA-50-5944 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c339545-c08a-4a77-b8e9-a7e49e53853f

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.7 years (25,440 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 373 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 764 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,750 days (4.8 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-50-5944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-50-5944-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 0.
- Sample TCGA-50-5944-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Acinar Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: R-Upper; Pulmonary function test indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,750 days; disease-specific survival: no event (censored), 1,750 days; disease-free interval: no event (censored), 1,750 days; progression-free interval: no event (censored), 1,750 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-50-5944-01A-11D-1752-01): tumor purity 0.57, ploidy 3.33, whole-genome doublings 1.
